Somatic mutation profile of tumor specimen TCGA-KN-8436-01A (aliquot TCGA-KN-8436-01A-11D-2310-10) from TCGA case TCGA-KN-8436, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 63.0 years (22,997 days).
Specimen TCGA-KN-8436-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fda8648-d4ea-4089-8e3b-526657452216.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8436-11A (Solid Tissue Normal), aliquot TCGA-KN-8436-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f4df524-233e-45d9-b719-695c3ebb38c7

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Frame Shift Del 2, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCE1 | c.1448A>G p.Y483C | Missense Mutation (SNP) | VAF 155/315 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs940202633, COSV99668762; called by muse, mutect2, varscan2
- ALG11 | c.24G>T p.W8C | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.417); catalogued as rs780498216, COSV99666870; called by muse, mutect2
- DENND5B | c.3652C>T p.L1218F | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100172011; called by muse, mutect2, varscan2
- GRIN3A | c.2105G>T p.G702V | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100701729; called by muse, mutect2, varscan2
- HNRNPF | c.1065A>T p.R355S | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.801); catalogued as COSV100563233; called by muse, mutect2, varscan2
- HSD11B2 | c.1047C>A p.F349L | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV99341297; called by muse, mutect2, varscan2
- KCNT1 | c.217G>A p.V73I (on ENST00000488444; = p.V92I on NM_020822.3) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as rs776233220, COSV53698199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A19 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs148139045, CM0910763, COSV58673636; called by muse, mutect2, varscan2
- SMCHD1 | c.1784C>A p.P595H | Missense Mutation (SNP) | VAF 230/476 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99862357; called by muse, mutect2, varscan2
- TP53 | c.1012T>A p.F338I | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV53045593, COSV53143038; called by muse, mutect2, varscan2
- ATP6AP1 | c.841_877del p.Q281Rfs*5 | Frame Shift Del (DEL) | VAF 61/84 reads (73%) | called by mutect2, pindel, varscan2
- FAT1 | c.3444del p.M1149Wfs*55 | Frame Shift Del (DEL) | VAF 79/211 reads (37%) | called by mutect2, pindel, varscan2
- OTOGL | c.1929C>T p.H643= (on ENST00000547103; = p.H634= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs150597873, COSV101509478; called by muse, mutect2, varscan2
- RESF1 | c.3066T>A p.P1022= | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as COSV100440545; called by muse, mutect2, varscan2
- NACA | c.71-4483dup | Intron (INS) | VAF 54/143 reads (38%) | called by mutect2, pindel, varscan2
